Gene-level copy-number profile of tumor specimen TARGET-20-PANCSC-04A from TARGET case TARGET-20-PANCSC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,890 days).
Specimen TARGET-20-PANCSC-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.9a2819af-8252-5d85-915e-555e9d783717.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PANCSC-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/dfa8badb-95ee-4232-91d7-aaa5c07bf7b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 525; copy number 2: 59,688; copy number 3: 61.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
